Somatic mutation profile of tumor specimen TCGA-LG-A9QC-01A (aliquot TCGA-LG-A9QC-01A-11D-A36X-10) from TCGA case TCGA-LG-A9QC, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 48.8 years (17,842 days).
Specimen TCGA-LG-A9QC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b7b831a2-b175-4719-91a5-b2f3d535dcb4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-LG-A9QC-10A (Blood Derived Normal), aliquot TCGA-LG-A9QC-10A-01D-A370-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/01f8653b-220e-4fd4-b5f8-27bd4afafdb2

The open-access MAF lists 55 somatic variants for this specimen: 43 protein-altering or splice-affecting, 10 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 10, Frame Shift Del 5, Splice Region 3, Intron 1, 5'Flank 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMZ1 | c.1246C>A p.Q416K | Missense Mutation (SNP) | VAF 43/132 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0.026); catalogued as COSV100406285; called by muse, mutect2, varscan2
- ANKS1A | c.895G>A p.A299T | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.989); catalogued as COSV100832224; called by muse, mutect2, varscan2
- ATP6V0E2 | c.11A>G p.H4R (on ENST00000425642; = p.H53R on NM_145230.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT tolerated (0.52); PolyPhen benign (0.035); catalogued as COSV101374575; called by muse, mutect2, varscan2
- C5 | c.1997A>G p.D666G | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.009); catalogued as COSV99797468; called by muse, mutect2, varscan2
- CACNA1S | c.976C>T p.L326F | Missense Mutation (SNP) | VAF 38/138 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779223763, COSV100754837; called by muse, mutect2, varscan2
- CEPT1 | c.356A>G p.Y119C | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.992); catalogued as rs1185046862, COSV100853459; called by muse, mutect2
- CFAP70 | c.1352T>A p.L451Q | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.694); catalogued as COSV100160367; called by muse, mutect2, varscan2
- CYP11B2 | c.548G>A p.S183N | Missense Mutation (SNP) | VAF 50/115 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as rs1351499256, COSV100010857; called by muse, mutect2, varscan2
- ERC1 | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.489); catalogued as rs1486634998, COSV100705790; called by muse, mutect2, varscan2
- FLOT2 | c.694A>G p.I232V | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV101204760; called by muse, varscan2
- FOXD1 | c.581G>A p.G194D | Missense Mutation (SNP) | VAF 85/360 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61076689; called by muse, mutect2, varscan2
- GALNT9 | c.1367T>C p.M456T (on ENST00000328957 / NM_001122636.2; = p.M90T on NM_021808.3) | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1422245011, COSV61096341; called by muse, mutect2, varscan2
- HIPK2 | c.2569T>A p.C857S | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT tolerated (0.27); PolyPhen benign (0.107); catalogued as COSV100702118; called by muse, mutect2, varscan2
- HR | c.1228G>T p.A410S | Missense Mutation (SNP) | VAF 32/45 reads (71%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV100455735; called by muse, mutect2, varscan2
- IL12RB1 | c.1617C>T p.I539= | Splice Region (SNP) | VAF 19/56 reads (34%) | catalogued as rs778430238, COSV101651886; called by muse, mutect2, varscan2
- IL21R | c.1058C>T p.P353L | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs550842554, COSV100559944; called by muse, mutect2
- KCNMA1 | c.1751T>C p.I584T | Missense Mutation (SNP) | VAF 4/94 reads (4%) | SIFT tolerated (0.8); PolyPhen benign (0.271); catalogued as COSV99696089; called by muse, mutect2
- KDM6A | c.3817del p.L1273Ffs*19 | Frame Shift Del (DEL) | VAF 67/109 reads (61%) | catalogued as COSV65039032; called by mutect2, pindel, varscan2
- KLRC4 | c.359G>A p.C120Y | Missense Mutation (SNP) | VAF 71/173 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100511274; called by muse, mutect2, varscan2
- LGALS7B | c.223C>T p.R75C | Missense Mutation (SNP) | VAF 100/265 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100153374; called by muse, mutect2, varscan2
- LRP2 | c.8276G>T p.R2759L | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV99787349, COSV99787722; called by muse, mutect2, varscan2
- MYH2 | c.3993C>A p.A1331= | Splice Region (SNP) | VAF 19/60 reads (32%) | catalogued as COSV99819689; called by muse, mutect2, varscan2
- MYH9 | c.1845G>A p.V615= | Splice Region (SNP) | VAF 22/55 reads (40%) | catalogued as COSV99338370, COSV99339987; called by muse, mutect2, varscan2
- MYLK4 | c.1004A>C p.K335T | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV51138758, COSV99193742; called by muse, mutect2, varscan2
- NPAS3 | c.2165A>T p.D722V (on ENST00000356141 / NM_001164749.2; = p.D690V on NM_022123.3) | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as COSV60841709; called by muse, mutect2, varscan2
- OBSCN | c.14832T>A p.H4944Q | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV99475451; called by muse, mutect2, varscan2
- PBRM1 | c.3859G>A p.E1287K (on ENST00000296302 / NM_001366071.2; = p.E1262K on NM_018313.5) | Missense Mutation (SNP) | VAF 25/36 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56270450; called by muse, mutect2, varscan2
- PLEKHG4 | c.2129G>A p.G710D | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.021); catalogued as COSV100430784; called by muse, mutect2, varscan2
- RNF44 | c.226G>T p.A76S | Missense Mutation (SNP) | VAF 76/248 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as COSV51270088; called by muse, mutect2, varscan2
- SCN9A | c.3850G>A p.G1284S (on ENST00000303354; = p.G1273S on NM_002977.3) | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.726); catalogued as COSV100312087; called by muse, mutect2, varscan2
- SPATA7 | c.52C>G p.P18A | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as COSV99247847; called by muse, mutect2, varscan2
- SPTBN4 | c.7536+1G>T p.X2512_splice | Splice Site (SNP) | VAF 20/76 reads (26%) | catalogued as COSV99399027; called by muse, mutect2, varscan2
- STPG2 | c.741C>G p.F247L | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99758663; called by muse, mutect2, varscan2
- TEX2 | c.970A>G p.S324G | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.942); catalogued as COSV99366932; called by muse, mutect2, varscan2
- TGOLN2 | c.368C>G p.T123S | Missense Mutation (SNP) | VAF 59/155 reads (38%) | SIFT tolerated (0.94); PolyPhen benign (0.003); catalogued as rs553348456, COSV99964991; called by muse, mutect2, varscan2
- YTHDC2 | c.2202A>G p.I734M | Missense Mutation (SNP) | VAF 63/260 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.058); catalogued as COSV99363079; called by muse, mutect2, varscan2
- ZNF397 | c.529T>A p.W177R | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV99734785; called by muse, mutect2, varscan2
- ADAMTSL3 | c.2604del p.L869Sfs*4 | Frame Shift Del (DEL) | VAF 26/70 reads (37%) | called by mutect2, varscan2
- CFAP36 | c.849del p.M284Cfs*3 | Frame Shift Del (DEL) | VAF 101/314 reads (32%) | called by mutect2, pindel, varscan2
- SRSF5 | c.747_763dup p.D255Gfs*27 | Frame Shift Ins (INS) | VAF 22/86 reads (26%) | called by mutect2, varscan2
- TERF2IP | c.149G>T p.G50V | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- TERF2IP | c.156_169del p.V53Gfs*20 | Frame Shift Del (DEL) | VAF 24/60 reads (40%) | called by pindel, varscan2
- ZNF687 | c.407del p.G136Efs*55 | Frame Shift Del (DEL) | VAF 28/98 reads (29%) | called by mutect2, pindel, varscan2
- DCD | c.303C>T p.D101= | Silent (SNP) | VAF 139/331 reads (42%) | catalogued as rs373661792; called by muse, mutect2, varscan2
- DNAH17 | c.2022C>T p.F674= | Silent (SNP) | VAF 18/73 reads (25%) | catalogued as COSV67758413; called by muse, mutect2, varscan2
- DNMT1 | c.4149A>C p.A1383= | Silent (SNP) | VAF 37/93 reads (40%) | catalogued as rs764029022, COSV100532178; ClinVar: likely benign; called by muse, mutect2, varscan2
- HECTD4 | c.5595C>T p.N1865= | Silent (SNP) | VAF 41/108 reads (38%) | catalogued as rs373022791; called by muse, mutect2, varscan2
- HS1BP3 | c.465C>T p.G155= | Silent (SNP) | VAF 27/64 reads (42%) | catalogued as rs570622489, COSV100397896; called by muse, mutect2, varscan2
- LRRN1 | c.882C>T p.I294= | Silent (SNP) | VAF 4/72 reads (6%) | catalogued as COSV100076370; called by muse, mutect2
- NME8 | c.444T>C p.C148= | Silent (SNP) | VAF 23/53 reads (43%) | catalogued as COSV99553036; called by muse, mutect2, varscan2
- REV3L | c.633A>G p.L211= | Silent (SNP) | VAF 27/65 reads (42%) | catalogued as COSV100725046; called by muse, mutect2, varscan2
- SP140 | c.2193C>A p.I731= | Silent (SNP) | VAF 85/303 reads (28%) | catalogued as COSV100613571; called by muse, mutect2, varscan2
- TMEM214 | c.285G>A p.V95= | Silent (SNP) | VAF 85/198 reads (43%) | catalogued as COSV99476149; called by muse, mutect2, varscan2
- ABCA2 | chr9:137033204 C>T | 5'Flank (SNP) | VAF 30/77 reads (39%) | catalogued as rs755505362; called by muse, mutect2, varscan2
- MACF1 | c.15832-11596C>T | Intron (SNP) | VAF 104/151 reads (69%) | catalogued as rs745896343, COSV99242810; called by muse, mutect2, varscan2
